Surgical pathology report (de-identified scan), TCGA case TCGA-85-8350, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8350-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

Asterand Case ID	Gross Description	Microscopic Description	Diagnosis Details	Comments	Formatted Path Report
					LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 1.2 x 2.5 x 3 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Right- upper

[page 2 of 2]
OpenClinica ID	Excision Date	Laterality
		Right-upper

Source: NCI Genomic Data Commons file db0c3a94-f7db-41fe-9335-d42df1b24383 (TCGA-85-8350.E784390F-9956-40F8-959D-01A869324D21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).